Somatic mutation profile of tumor specimen TCGA-85-8666-01A (aliquot TCGA-85-8666-01A-11D-2395-08) from TCGA case TCGA-85-8666, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-85-8666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ffb2afa-8c10-4b0e-91cf-5a3ba4168fe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8666-10A (Blood Derived Normal), aliquot TCGA-85-8666-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2f2e1a-aa43-4ba4-b8b0-6fb81dad3b6b

The open-access MAF lists 248 somatic variants for this specimen: 186 protein-altering or splice-affecting, 61 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 61, Nonsense Mutation 9, Frame Shift Del 6, Splice Site 5, Frame Shift Ins 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs397508256, CM970260, COSV99135139; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- AACS | c.1577G>A p.R526K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99907901; called by muse, mutect2, varscan2
- ABCA1 | c.3185G>C p.G1062A | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036779, COSV66066638; called by muse, mutect2, varscan2
- ABL2 | c.703G>C p.E235Q (on ENST00000502732 / NM_007314.4; = p.E220Q on NM_005158.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100772627, COSV100773109; called by muse, mutect2
- ADAMTS12 | c.1782C>A p.H594Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV100710617; called by muse, mutect2, varscan2
- ADGRL2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs780325031, COSV99588122; called by muse, mutect2, varscan2
- AK5 | c.208C>A p.L70I (on ENST00000354567 / NM_174858.3; = p.L44I on NM_012093.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.883); catalogued as COSV100481419; called by muse, mutect2, varscan2
- AKNA | c.1926G>T p.E642D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99800074; called by muse, mutect2, varscan2
- ANKRD30A | c.1667C>A p.S556Y (on ENST00000611781; = p.S500Y on NM_052997.2) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100653252, COSV64608220; called by muse, mutect2, varscan2
- ANO3 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881889; called by muse, mutect2, varscan2
- AOAH | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99332485, COSV99333954; called by muse, mutect2, varscan2
- APC | c.6460C>G p.Q2154E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs1003613894, COSV99966950; ClinVar: uncertain significance; called by muse, mutect2
- APC | c.7163C>T p.A2388V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV99966952; called by muse, mutect2
- ARHGAP17 | c.2522A>C p.N841T (on ENST00000289968 / NM_001006634.3; = p.N763T on NM_018054.6) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV99253238; called by muse, mutect2, varscan2
- ARHGAP26 | c.2204G>A p.C735Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.085); catalogued as COSV99190407; called by muse, mutect2, varscan2
- ARHGAP6 | c.2369T>C p.L790P (on ENST00000337414 / NM_013427.3; = p.L587P on NM_013423.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as COSV100272664; called by mutect2, varscan2
- ARHGEF1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV61529530; called by muse, mutect2, varscan2
- ASXL1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs1005458245, COSV60104557; called by muse, mutect2, varscan2
- BBX | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361327; called by muse, mutect2, varscan2
- BRINP3 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100818622; called by muse, mutect2, varscan2
- BSN | c.6574G>A p.G2192S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607946; called by muse, mutect2, varscan2
- CACNA1G | c.3629G>T p.R1210L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61742848; called by muse, mutect2, varscan2
- CACNA1S | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100754871; called by muse, mutect2, varscan2
- CCDC88A | c.3414A>C p.E1138D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99710154; called by muse, mutect2, varscan2
- CCL15 | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs1281381021; called by muse, mutect2, varscan2
- CD37 | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV100114945; called by muse, mutect2, varscan2
- CD69 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV99946037; called by muse, mutect2, varscan2
- CD69 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV99946039; called by muse, mutect2, varscan2
- CELSR1 | c.5057A>C p.Q1686P | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99417684; called by muse, mutect2, varscan2
- CEP350 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV100854460; called by muse, mutect2
- CES1 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV100828620; called by muse, mutect2, varscan2
- CLIC5 | c.1115G>T p.G372V (on ENST00000185206 / NM_001370649.1; = p.G213V on NM_016929.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99484211; called by muse, mutect2, varscan2
- COL19A1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100505938, COSV59571242; called by muse, mutect2, varscan2
- CPZ | c.929C>T p.T310M (on ENST00000360986 / NM_001014447.3; = p.T299M on NM_003652.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs780359404, COSV100248900; called by muse, mutect2, varscan2
- CSMD3 | c.9571del p.V3191Lfs*17 (on ENST00000297405 / NM_001363185.1; = p.V3022Lfs*17 on NM_052900.3) | Frame Shift Del (DEL) | VAF 49/161 reads (30%) | catalogued as COSV52104127; called by mutect2, pindel, varscan2
- CSMD3 | c.3142C>A p.L1048I (on ENST00000297405 / NM_001363185.1; = p.L944I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs1038971284, COSV52100311, COSV52199877, COSV52252257; called by muse, mutect2
- CSPG4 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774099952, COSV57899615; called by mutect2, varscan2
- CUL3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV104388443, COSV52364003; called by muse, mutect2, varscan2
- CXXC5 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100210651; called by muse, mutect2, varscan2
- CYP7B1 | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100041266; called by muse, mutect2, varscan2
- DLC1 | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs148727515, COSV52324792; called by muse, mutect2, varscan2
- DPH2 | c.1086T>G p.C362W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as COSV52543848, COSV99356389; called by muse, mutect2, varscan2
- DPP10 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59686894; called by muse, mutect2, varscan2
- DPP4 | c.1568-1G>T p.X523_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100858790; called by muse, mutect2, varscan2
- DRAM2 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99713365; called by muse, mutect2, varscan2
- DRD2 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV100669489; called by muse, mutect2, varscan2
- EIF3A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100974564; called by muse, mutect2, varscan2
- EPG5 | c.1856C>G p.S619* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99956964; called by muse, mutect2, varscan2
- ERICH3 | c.2341C>A p.P781T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100443923; called by muse, mutect2, varscan2
- ERP27 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs753773967, COSV99844261; called by muse, mutect2, varscan2
- EXOC4 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.114); catalogued as rs753618140, COSV99553227; called by muse, mutect2, varscan2
- FBN3 | c.6344A>G p.Y2115C | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99560537; called by muse, mutect2, varscan2
- FGD3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.066); catalogued as COSV100490499; called by muse, mutect2
- FHOD3 | c.3124G>A p.E1042K (on ENST00000359247 / NM_001281739.3; = p.E1059K on NM_025135.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765159862, COSV99940793; called by muse, mutect2, varscan2
- FLRT2 | c.1724A>G p.Q575R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV100420224; called by muse, mutect2, varscan2
- FRMD6 | c.100-2A>T p.X34_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV61086820; called by muse, mutect2, varscan2
- FRMPD1 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899518; called by muse, mutect2, varscan2
- GALNT17 | c.776T>A p.V259D | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100353309; called by muse, mutect2, varscan2
- GJA8 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV99569263, COSV99569526; called by muse, mutect2, varscan2
- GPX5 | c.441del p.V148Sfs*5 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as COSV101297291; called by mutect2, pindel, varscan2
- GRIA4 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV56895769; called by muse, mutect2, varscan2
- GRIK3 | c.2038del p.T680Pfs*14 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as COSV66140885; called by mutect2, pindel, varscan2
- GRM8 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281923; called by muse, mutect2, varscan2
- GTSF1 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100007471; called by muse, mutect2, varscan2
- H2AC13 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100704354; called by muse, mutect2, varscan2
- HADHB | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 19/111 reads (17%) | catalogued as COSV100501962; called by muse, mutect2, varscan2
- HEATR1 | c.521C>G p.A174G | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100857194; called by muse, mutect2, varscan2
- HTR3B | c.262T>A p.W88R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491882; called by muse, mutect2, varscan2
- HTR6 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99230049; called by muse, mutect2, varscan2
- IFT81 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV99655882; called by muse, mutect2, varscan2
- IGSF10 | c.1437C>A p.N479K | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV99177525; called by muse, mutect2
- IGSF9B | c.3793G>T p.G1265W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV100317353; called by muse, mutect2, varscan2
- JUNB | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.425); catalogued as COSV100040151; called by muse, mutect2
- KAT8 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99571316; called by muse, mutect2, varscan2
- KCNJ1 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100131298; called by muse, mutect2, varscan2
- KCTD8 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100759423; called by muse, mutect2, varscan2
- KDM5A | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV101238726; called by muse, mutect2
- KIAA1328 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV99693920; called by muse, mutect2, varscan2
- KIF26B | c.6027G>C p.K2009N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100832038; called by muse, mutect2, varscan2
- KLKB1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249816; called by muse, mutect2, varscan2
- KMT2C | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1402089231, COSV51520636; called by muse, mutect2, varscan2
- KRTCAP3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs187699375; called by muse, mutect2, varscan2
- LAMC3 | c.3172C>A p.P1058T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100735937; called by muse, mutect2, varscan2
- LEFTY1 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV99686477; called by muse, mutect2, varscan2
- LRP5 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030681, COSV99591742; called by muse, mutect2
- LRRFIP2 | c.598A>C p.S200R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100368305; called by muse, mutect2, varscan2
- LYST | c.10535G>C p.C3512S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as rs1181666827, COSV101088925; called by muse, mutect2, varscan2
- MAP2 | c.1479G>T p.M493I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99559106; called by muse, mutect2, varscan2
- MFSD6L | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV61004837; called by muse, mutect2, varscan2
- MSTN | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99640622, COSV99640732; called by muse, mutect2, varscan2
- MUC16 | c.3583T>G p.L1195V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV101199320; called by muse, mutect2, varscan2
- MYH4 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99700921; called by muse, mutect2, varscan2
- MYH7 | c.5317C>A p.Q1773K | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs730880815, COSV100805933, COSV62522704; ClinVar: uncertain significance; called by muse, mutect2
- MYO10 | c.5935G>T p.A1979S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.386); catalogued as COSV99945104; called by muse, mutect2
- NADSYN1 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034607; called by muse, mutect2, varscan2
- NCAM2 | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as COSV99522460; called by muse, mutect2, varscan2
- NHS | c.2704A>G p.K902E | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV101196517; called by muse, mutect2, varscan2
- NIBAN1 | c.727A>T p.N243Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV100836357; called by muse, mutect2, varscan2
- NLRP10 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100149604; called by muse, mutect2
- NOX3 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99342964; called by muse, mutect2, varscan2
- NPTX2 | c.1008G>C p.E336D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs113547096, COSV99674802; called by muse, mutect2, varscan2
- OR10G7 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100389872; called by muse, mutect2
- OR2T10 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100393631; called by muse, mutect2, varscan2
- OR2T4 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 32/213 reads (15%) | catalogued as COSV63545133; called by muse, mutect2, varscan2
- OR4C11 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100155287; called by muse, mutect2
- OR4D5 | c.131T>A p.L44H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100189855; called by muse, mutect2, varscan2
- OR4D6 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100271652; called by muse, mutect2, varscan2
- OR4K1 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53458965, COSV99578828; called by muse, varscan2
- OR5B3 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100511957; called by mutect2, varscan2
- PCDHGA10 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV53947239; called by muse, mutect2, varscan2
- PCDHGB5 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV53909297; called by muse, mutect2, varscan2
- PDYN | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV99452908; called by muse, mutect2, varscan2
- PEG3 | c.2858A>G p.H953R | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV99688324; called by muse, mutect2, varscan2
- PEX11B | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100355251, COSV57163156; called by muse, mutect2, varscan2
- PIK3C2B | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100916050; called by muse, mutect2, varscan2
- PLA2G4C | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100843893; called by muse, mutect2, varscan2
- PNLIP | c.910T>A p.S304T | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100981740; called by muse, mutect2, varscan2
- POLQ | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369056683, COSV99951428; called by muse, mutect2, varscan2
- PRDM5 | c.1535C>A p.T512K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99310307; called by muse, mutect2, varscan2
- PRDM9 | c.950+1G>T p.X317_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99690210; called by muse, mutect2, varscan2
- PRDM9 | c.2589G>T p.R863S | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.326); catalogued as rs538854128, COSV99690211; called by muse, mutect2, varscan2
- PREX1 | c.784-2A>G p.X262_splice | Splice Site (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100906165; called by muse, mutect2, varscan2
- PRKDC | c.12245G>A p.R4082Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs778808256, COSV100043243, COSV58070439; called by muse, mutect2, varscan2
- PSMD5 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV99270729; called by muse, mutect2, varscan2
- RAD51AP1 | c.601G>T p.A201S (on ENST00000228843 / NM_001130862.2; = p.A184S on NM_006479.5) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV99961217; called by muse, mutect2, varscan2
- RANBP2 | c.4484G>A p.S1495N | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs780627738, COSV99311776; called by muse, mutect2, varscan2
- RASD2 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99332735; called by muse, mutect2, varscan2
- RCVRN | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV56840876, COSV99874138; called by muse, mutect2
- RFC5 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57477616; called by muse, mutect2, varscan2
- RPS5 | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99544867; called by muse, mutect2, varscan2
- RPUSD1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.912); catalogued as COSV99135699; called by muse, mutect2, varscan2
- RTL5 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV101029985, COSV65453092; called by muse, mutect2, varscan2
- SACS | c.10105G>T p.V3369F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV101207332; called by muse, mutect2, varscan2
- SATB2 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.158); catalogued as COSV99610953; called by muse, mutect2, varscan2
- SCN3A | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1229864715, COSV51818088; called by muse, mutect2, varscan2
- SDS | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99981007; called by muse, mutect2, varscan2
- SEPTIN11 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99346242; called by muse, varscan2
- SEPTIN2 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 115/414 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV100764928; called by muse, mutect2, varscan2
- SHE | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as COSV100495946; called by muse, mutect2, varscan2
- SIN3A | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV100845116; called by muse, mutect2, varscan2
- SIPA1L3 | c.1402C>A p.R468S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1452266016, COSV55921950, COSV99728163; called by muse, mutect2, varscan2
- SLC1A7 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101019500; called by muse, mutect2, varscan2
- SLC26A9 | c.2155G>T p.G719W | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536245; called by muse, mutect2, varscan2
- SLC2A14 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs751889509, COSV100533723; called by muse, mutect2, varscan2
- SLC39A12 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101069996; called by muse, mutect2, varscan2
- SLC39A5 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99907419; called by muse, mutect2, varscan2
- SLC8A1 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | catalogued as COSV100245503; called by muse, mutect2, varscan2
- SLC9C2 | c.2692G>T p.G898C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876685, COSV62947712; called by muse, mutect2, varscan2
- SORCS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs377202317; called by muse, mutect2, varscan2
- SPICE1 | c.2548C>T p.L850F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs778692837, COSV99869307; called by muse, mutect2
- SPTA1 | c.2533C>A p.H845N | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63751616; called by muse, mutect2, varscan2
- SPTBN1 | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100442260; called by muse, mutect2, varscan2
- STAC | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs754667535, COSV56219974, COSV99829785; called by muse, mutect2, varscan2
- TEX30 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101051993; called by muse, mutect2, varscan2
- TGFBR2 | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV99846862; called by mutect2, varscan2
- TIMP3 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV99831059; called by muse, mutect2
- TLR4 | c.527A>T p.N176I (on ENST00000355622 / NM_138554.5; = p.N136I on NM_003266.4) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100790630; called by muse, mutect2
- TMCO4 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs113501810; called by muse, mutect2, varscan2
- TMEM14B | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101077415; called by muse, mutect2, varscan2
- TMF1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV101275420, COSV68375568; called by muse, mutect2, varscan2
- TNC | c.4897C>T p.P1633S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.217); catalogued as COSV100405467, COSV60786022; called by muse, mutect2, varscan2
- TP53 | c.250del p.A84Pfs*39 | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | catalogued as COSV53077353; called by mutect2, pindel, varscan2
- TRIM3 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100624339; called by muse, mutect2, varscan2
- TRIP11 | c.3052A>T p.T1018S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV99970536; called by muse, mutect2, varscan2
- TTN | c.97001T>C p.L32334P (on ENST00000591111; = p.L24910P on NM_003319.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | PolyPhen benign (0.312); catalogued as COSV100604372; called by muse, mutect2, varscan2
- UPF2 | c.3014G>T p.R1005L | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100707145; called by muse, mutect2, varscan2
- USP8 | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV100208909, COSV56162792; called by muse, mutect2, varscan2
- WASF3 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100098443; called by muse, mutect2, varscan2
- WWOX | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs774783221, COSV101282928; called by muse, mutect2, varscan2
- ZBED9 | c.3691G>T p.A1231S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.992); catalogued as COSV101509196; called by muse, mutect2, varscan2
- ZNF14 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV100694029; called by muse, mutect2, varscan2
- ZNF215 | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99549467; called by muse, mutect2
- ZNF324 | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99543212; called by muse, mutect2
- ZNF324 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV99543218; called by muse, mutect2, varscan2
- ZNF385B | c.1242+1G>C p.X414_splice | Splice Site (SNP) | VAF 36/178 reads (20%) | catalogued as COSV100415925; called by muse, mutect2, varscan2
- ZNF676 | c.673G>T p.G225* (on ENST00000650058; = p.G193* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV101236156; called by muse, mutect2, varscan2
- ZNF804A | c.384A>G p.V128= | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100167278; called by muse, mutect2, varscan2
- ZNF804A | c.2208C>G p.H736Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV100167280; called by muse, mutect2, varscan2
- ZNF883 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV101432545; called by muse, mutect2, varscan2
- ALG2 | c.435_436insCG p.K146Rfs*18 | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | called by mutect2, pindel*, varscan2*
- CDKN2A | c.227_230del p.A76Vfs*69 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- FSHR | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NRXN1 | c.2656_2657insC p.G886Afs*7 | Frame Shift Ins (INS) | VAF 13/47 reads (28%) | called by mutect2, pindel*, varscan2
- RBP3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF417 | c.384C>G p.N128K | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ZNF831 | c.3955_3956del p.S1319Pfs*7 | Frame Shift Del (DEL) | VAF 13/167 reads (8%) | called by muse*, mutect2
- ADAMDEC1 | c.675G>A p.V225= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1239116099, COSV99835973; called by muse, mutect2
- ADCY5 | c.3780C>G p.L1260= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV100567541; called by muse, mutect2, varscan2
- AEN | c.582G>T p.A194= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV100237389, COSV60429302; called by muse, mutect2, varscan2
- AL592490.1 | c.1629C>T p.T543= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV101308137; called by muse, mutect2, varscan2
- ANO3 | c.1143G>C p.L381= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99881887; called by muse, mutect2, varscan2
- ARHGAP15 | c.1374A>T p.I458= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV99709748; called by muse, mutect2, varscan2
- ARHGAP21 | c.2040G>A p.G680= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100256019; called by muse, mutect2, varscan2
- ASPH | c.1386G>T p.V462= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV101063700; called by muse, mutect2, varscan2
- BARD1 | c.778T>C p.L260= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99638417; called by muse, mutect2, varscan2
- BTG2 | c.402C>T p.L134= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99305708; called by muse, mutect2, varscan2
- CCNG2 | c.288A>G p.K96= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs777185716, COSV100313105; called by muse, mutect2, varscan2
- CDH6 | c.1014A>G p.E338= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV54067918; called by muse, mutect2, varscan2
- CR1L | c.126A>G p.P42= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV99687071; called by muse, mutect2, varscan2
- CYP27C1 | c.171A>C p.S57= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV100079771; called by muse, mutect2, varscan2
- DNAH10 | c.4098C>G p.L1366= (on ENST00000409039; = p.L1305= on NM_207437.3) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV68993340; called by muse, mutect2, varscan2
- DNAH11 | c.5283G>T p.L1761= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100178509; called by muse, mutect2, varscan2
- EPCAM | c.540T>C p.F180= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99764102; called by muse, mutect2, varscan2
- EPHA4 | c.2040G>C p.P680= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV56032313, COSV99916182; called by muse, mutect2, varscan2
- GAS8 | c.564G>A p.K188= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99243896; called by muse, mutect2, varscan2
- HELZ2 | c.2925G>A p.E975= (on ENST00000467148 / NM_001037335.2; = p.E406= on NM_033405.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100915523; called by muse, mutect2, varscan2
- HSPB2 | c.258C>T p.D86= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as rs141344478; called by muse, mutect2, varscan2
- KCNH7 | c.984C>A p.T328= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100035088; called by muse, mutect2, varscan2
- KCNQ5 | c.2106C>T p.F702= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV100571774, COSV59656750; called by muse, mutect2, varscan2
- MACROD2 | c.1119G>T p.S373= (on ENST00000642719; = p.S345= on NM_080676.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs748741601, COSV54018764, COSV99429734; called by muse, mutect2
- MAGEB2 | c.759G>T p.V253= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100975631; called by muse, mutect2, varscan2
- MBL2 | c.726C>A p.A242= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as rs139905034, COSV64759062; called by muse, mutect2, varscan2
- MLPH | c.1212G>A p.E404= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99222077; called by muse, mutect2, varscan2
- MUC5B | c.11133C>A p.T3711= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV101500219; called by muse, mutect2
- NFS1 | c.270C>T p.S90= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100148706; called by muse, mutect2, varscan2
- NLGN4X | c.651A>C p.A217= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99321041; called by muse, mutect2, varscan2
- NRG3 | c.267C>A p.I89= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1473261428, COSV100931158; called by muse, mutect2
- OR10J1 | c.697C>A p.R233= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs1016467615, COSV101419826, COSV71128897; called by muse, mutect2, varscan2
- OR2L2 | c.60A>G p.S20= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as rs973328099, COSV100823386; called by muse, mutect2, varscan2
- OR2L3 | c.423G>T p.V141= | Silent (SNP) | VAF 31/242 reads (13%) | catalogued as COSV63455320; called by muse, mutect2, varscan2
- OR8K3 | c.645T>G p.L215= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100449732; called by muse, mutect2, varscan2
- PATJ | c.1290C>G p.A430= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV100333769; called by muse, mutect2
- PCDHB14 | c.1275C>T p.D425= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV99505740; called by muse, mutect2, varscan2
- PCDHB2 | c.693G>T p.R231= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99523012; called by muse, mutect2, varscan2
- PGM5 | c.1152T>C p.F384= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV101123406; called by muse, mutect2
- PLCB1 | c.2964A>T p.S988= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100570219; called by muse, mutect2
- PLD5 | c.729G>T p.L243= (on ENST00000442594; = p.L181= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100139742, COSV100141854; called by muse, mutect2, varscan2
- PLEKHO2 | c.732C>T p.S244= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100060654; called by muse, mutect2, varscan2
- PRAMEF19 | c.105C>A p.L35= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- PRMT3 | c.786T>G p.V262= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100423819; called by muse, mutect2, varscan2
- RAB21 | c.285G>T p.A95= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99714732; called by muse, mutect2, varscan2
- RABL6 | c.1386C>T p.V462= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100273164; called by muse, mutect2
- RIMS2 | c.3075A>C p.A1025= (on ENST00000666250 / NM_001348490.2; = p.A833= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99166063, COSV99202564; called by muse, mutect2, varscan2
- SACS | c.10635G>A p.V3545= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as CD1515358, COSV101207330; called by muse, mutect2
- SIK2 | c.2499A>G p.R833= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100232060; called by muse, mutect2, varscan2
- SLC22A14 | c.12G>A p.E4= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs746974172, COSV99828188; called by muse, mutect2, varscan2
- SLC25A13 | c.1734G>T p.L578= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV99673355; called by muse, mutect2, varscan2
- SPEF2 | c.1644G>C p.A548= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100606940; called by muse, mutect2
- THSD7A | c.2901G>T p.G967= | Silent (SNP) | VAF 45/208 reads (22%) | catalogued as COSV101448619, COSV70262332; called by muse, mutect2, varscan2
- TNMD | c.390T>A p.P130= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100887834; called by muse, mutect2, varscan2
- TNN | c.1263C>T p.I421= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99511630; called by muse, mutect2
- TSHZ1 | c.2193G>C p.G731= (on ENST00000580243 / NM_001308210.2; = p.G686= on NM_005786.6) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1266485367, COSV100433527, COSV59018347; called by muse, mutect2, varscan2
- TYW1 | c.633G>T p.G211= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs145265045; called by muse, mutect2, varscan2
- ZMYND8 | c.1596G>C p.L532= (on ENST00000311275 / NM_001363741.2; = p.L552= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/85 reads (5%) | catalogued as COSV99520090; called by muse, mutect2
- ZNF324 | c.286C>A p.R96= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV52180595, COSV99543213; called by muse, mutect2
- ZNF33A | c.1254G>A p.G418= (on ENST00000458705 / NM_006974.3; = p.G419= on NM_006954.2) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100275658; called by muse, mutect2
- ZNF43 | c.1683T>A p.T561= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100731769; called by muse, mutect2
- ADHFE1 | c.888-346C>T | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as rs1322597633, COSV99397711; called by muse, mutect2, varscan2
